Somatic mutation profile of tumor specimen TCGA-EE-A2GO-06A (aliquot TCGA-EE-A2GO-06A-11D-A196-08) from TCGA case TCGA-EE-A2GO, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Amelanotic melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 72.1 years (26,322 days).
Specimen TCGA-EE-A2GO-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c224183-4c0c-4781-9dde-89d3e9a85ca0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GO-10A (Blood Derived Normal), aliquot TCGA-EE-A2GO-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9419a5d-6c3f-41f9-8231-e54644c70d1d

The open-access MAF lists 2,430 somatic variants for this specimen: 1,507 protein-altering or splice-affecting, 859 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,367, Silent 859, Nonsense Mutation 92, Splice Site 24, Intron 21, RNA 19, Splice Region 16, 3'Flank 9, 5'UTR 7, Frame Shift Del 5, 3'UTR 5, 5'Flank 3.

Variants (750 of 2,430; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1525G>A p.G509R (on ENST00000288602 / NM_001374244.1; = p.G469R on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs121913357, BM1457681, COSV56070557, COSV56082352, COSV99953015; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.8608C>T p.Q2870* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as rs587782010, COSV66463224; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH9 | c.7102G>A p.E2368K | Missense Mutation (SNP) | VAF 30/96 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as rs140313224, COSV52337194; called by muse, mutect2, varscan2
- GRXCR1 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as rs761349153, CM153971, COSV67670021; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 105/159 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs28933406, COSV54236740, COSV54240324, COSV54242140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NEXMIF | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as rs878854425, COSV50022161; ClinVar: pathogenic; called by mutect2, varscan2
- A1CF | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV50957343, COSV51028098; called by muse, mutect2, varscan2
- AADAC | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV51761374; called by muse, mutect2
- AADACL3 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 37/41 reads (90%) | catalogued as COSV60200616; called by muse, mutect2, varscan2
- AAR2 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as rs759400956, COSV57925058; called by muse, mutect2, varscan2
- ABAT | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.496); catalogued as rs750680169, COSV51628725; called by muse, mutect2, varscan2
- ABCA12 | c.5404G>A p.A1802T (on ENST00000272895 / NM_173076.3; = p.A1484T on NM_015657.3) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.102); catalogued as rs1559123915, COSV55977326; called by muse, mutect2, varscan2
- ABCA12 | c.1246G>A p.E416K (on ENST00000272895 / NM_173076.3; = p.E98K on NM_015657.3) | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.171); catalogued as COSV55977348; called by muse, mutect2, varscan2
- ABCA13 | c.2912A>T p.Y971F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.311); catalogued as COSV70045643; called by muse, mutect2, varscan2
- ABCA13 | c.10400C>T p.S3467F | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs763985029, COSV71283671; called by muse, mutect2, varscan2
- ABCA3 | c.4006C>T p.L1336F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100069263; called by muse, mutect2, varscan2
- ABCB10 | c.817A>T p.N273Y | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60624385; called by muse, mutect2, varscan2
- ABCB5 | c.3079C>T p.R1027C (on ENST00000404938 / NM_001163941.2; = p.R582C on NM_178559.6) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs773162567, COSV51704137; called by muse, mutect2, varscan2
- ABCC1 | c.2941C>A p.L981I | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); catalogued as COSV60695062; called by muse, varscan2
- ABCC2 | c.4529G>A p.G1510E | Missense Mutation (SNP) | VAF 53/59 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64988769; called by muse, mutect2, varscan2
- ABCC6 | c.1862G>A p.G621E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.055); catalogued as COSV52748167; called by muse, mutect2
- ABCC9 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs746967404, COSV53962075, COSV53967382; called by mutect2, varscan2
- ABCG1 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs376798940; called by muse, mutect2, varscan2
- ABHD12B | c.361G>A p.E121K (on ENST00000337334 / NM_001206673.2; = p.E44K on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs368157046, COSV61569773, COSV61570289; called by muse, mutect2, varscan2
- ABI3BP | c.3197G>A p.G1066E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52552618; called by muse, mutect2, varscan2
- ABRA | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV61732920; called by muse, mutect2, varscan2
- AC008397.2 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as rs746162922, COSV53206219, COSV53208687; called by muse, mutect2, varscan2
- AC018630.4 | c.364T>C p.S122P | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57392719; called by muse, varscan2
- AC244197.3 | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV61714944; called by muse, mutect2, varscan2
- ACACA | c.5302C>T p.R1768C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1348929671; called by muse, mutect2, varscan2
- ACAN | c.7121C>T p.P2374L (on ENST00000560601 / NM_001369268.1; = p.P2298L on NM_001135.3) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs761543122, COSV61360718, COSV61370279; called by muse, mutect2, varscan2
- ACE | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.332); catalogued as rs992848550, CD120956, COSV52013603; called by muse, mutect2, varscan2
- ACKR2 | c.678G>A p.M226I | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV56180581; called by muse, mutect2, varscan2
- ACMSD | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs776772158, COSV51609990; called by muse, mutect2, varscan2
- ACP5 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54537692; called by muse, mutect2, varscan2
- ACSBG1 | c.1802G>A p.G601E | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51911333; called by muse, mutect2, varscan2
- ACSBG1 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51911342; called by muse, mutect2, varscan2
- ACSF2 | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 48/90 reads (53%) | catalogued as rs770755181, COSV51956416; called by muse, mutect2, varscan2
- ACSL1 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as rs1430794011, COSV55666839; called by muse, mutect2, varscan2
- ACSM1 | c.1361G>A p.G454D | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV54640504; called by muse, mutect2, varscan2
- ACSM5 | c.1207-2A>G p.X403_splice | Splice Site (SNP) | VAF 19/51 reads (37%) | catalogued as COSV59375283; called by muse, mutect2, varscan2
- ACTBL2 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV70661863; called by muse, mutect2, varscan2
- ACTBL2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as rs749694409, COSV70661456; called by mutect2, varscan2
- ADAM12 | c.2299C>T p.H767Y | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV64115373; called by mutect2, varscan2
- ADAM18 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs1430197793, COSV55856085; called by muse, mutect2, varscan2
- ADAM2 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs768366466, COSV55869035; called by mutect2, varscan2
- ADAM21 | c.782G>C p.W261S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50811947; called by muse, mutect2, varscan2
- ADAM21 | c.783G>A p.W261* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99961591; called by mutect2, varscan2
- ADAM21 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.03); catalogued as COSV50812063, COSV50813379; called by muse, mutect2, varscan2
- ADAM22 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV55994413, COSV99718737; called by muse, mutect2, varscan2
- ADAM32 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV101165458, COSV65953974, COSV65954546; called by muse, mutect2, varscan2
- ADAMTS10 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); catalogued as COSV54359945; called by muse, mutect2, varscan2
- ADAMTS7 | c.3217C>T p.H1073Y | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV66309581; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4016C>T p.S1339F | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); catalogued as rs1248868520, COSV54472201; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1357463642, COSV99648261; called by muse, mutect2, varscan2
- ADAP2 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV100437396; called by muse, mutect2, varscan2
- ADAR | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV52721768; called by muse, mutect2, varscan2
- ADCY10 | c.3717G>A p.M1239I | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV63245335; called by muse, mutect2, varscan2
- ADCY8 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53903634; called by muse, mutect2, varscan2
- ADGRB1 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); catalogued as COSV60103798; called by muse, mutect2, varscan2
- ADGRB2 | c.4432C>T p.R1478W (on ENST00000373658 / NM_001364857.2; = p.R1477W on NM_001294335.2) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201415816, COSV57079751; called by muse, mutect2, varscan2
- ADGRB3 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 100/112 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369405391, COSV65394023; called by muse, varscan2
- ADGRD1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.304); catalogued as rs764392187, COSV55443294, COSV55443584, COSV99895751; called by muse, mutect2, varscan2
- ADGRD1 | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV55447780; called by muse, mutect2, varscan2
- ADGRF5 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs975550070, COSV51935391; called by muse, mutect2, varscan2
- ADGRG4 | c.8377G>A p.V2793I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV54967705; called by muse, varscan2
- ADGRG4 | c.8552T>C p.L2851P | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54967714; called by muse, varscan2
- ADGRV1 | c.4984C>T p.R1662C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs913229037, COSV67996315; called by mutect2, varscan2
- ADGRV1 | c.10772C>T p.S3591L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.104); catalogued as rs75732872, COSV67996322; called by muse, mutect2, varscan2
- ADGRV1 | c.17029G>A p.E5677K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV67996325; called by mutect2, varscan2
- ADH1A | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52926311; called by muse, mutect2, varscan2
- ADIPOQ | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202043211, COSV57860142; called by muse, mutect2, varscan2
- ADORA1 | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 63/312 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV58808696, COSV58813370; called by muse, mutect2, varscan2
- ADRA1D | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV65242105; called by muse, mutect2, varscan2
- ADRA2A | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated (0.12); PolyPhen benign (0.381); catalogued as COSV54530218; called by muse, mutect2, varscan2
- AEBP1 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); catalogued as COSV56261617; called by muse, mutect2
- AGAP1 | c.2537G>A p.R846Q (on ENST00000304032 / NM_001037131.3; = p.R793Q on NM_014914.5) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as rs544625578, COSV58327072; called by muse, mutect2
- AGAP2 | c.2600G>A p.R867K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.98); catalogued as COSV57732467; called by muse, mutect2
- AGBL4 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV100484691; called by muse, mutect2, varscan2
- AGBL5 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); catalogued as COSV59938579; called by muse, mutect2, varscan2
- AGK | c.19A>C p.T7P | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV62596075; called by muse, mutect2, varscan2
- AGPAT4 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV57251718; called by muse, mutect2, varscan2
- AHSG | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.137); catalogued as COSV56608340, COSV56609521; called by muse, mutect2, varscan2
- AIRE | c.1098C>T p.L366= | Splice Region (SNP) | VAF 29/90 reads (32%) | catalogued as COSV52398550; called by muse, mutect2, varscan2
- AIRE | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs950789600, COSV52397198, COSV99381198; called by muse, mutect2, varscan2
- AK7 | c.1975-1G>A p.X659_splice | Splice Site (SNP) | VAF 15/37 reads (41%) | catalogued as COSV50883457; called by muse, mutect2, varscan2
- AKAP4 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs147442985, COSV62073813; called by muse, mutect2, varscan2
- AKNA | c.3697C>T p.P1233S | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV56340580; called by muse, mutect2, varscan2
- AL592490.1 | c.2749G>A p.E917K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868417297, COSV69427161; called by muse, mutect2, varscan2
- AL645922.1 | c.3455G>A p.G1152E | Missense Mutation (SNP) | VAF 144/258 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64888607; called by muse, mutect2, varscan2
- ALB | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55743030; called by muse, mutect2, varscan2
- ALB | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs751923567, COSV55743047; called by muse, mutect2, varscan2
- ALB | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as COSV55743057; called by muse, varscan2
- ALB | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.85); catalogued as COSV55738874; called by muse, mutect2, varscan2
- ALG1 | c.68G>A p.W23* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as rs1360917125; called by muse, mutect2, varscan2
- ALOX12 | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.948); catalogued as COSV52349715; called by muse, mutect2, varscan2
- ALPG | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54965236, COSV54965746; called by muse, mutect2, varscan2
- ALPK2 | c.2392A>T p.R798* | Nonsense Mutation (SNP) | VAF 13/20 reads (65%) | catalogued as COSV64497653; called by muse, mutect2, varscan2
- ALPK3 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV51940637; called by muse, mutect2, varscan2
- ALPL | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100876208, COSV66376688; called by muse, mutect2, varscan2
- AMER1 | c.1670A>T p.E557V | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57669868; called by mutect2, varscan2
- AMOT | c.3199C>T p.P1067S (on ENST00000371959 / NM_001113490.1; = p.P658S on NM_133265.3) | Missense Mutation (SNP) | VAF 149/514 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV59068917; called by muse, mutect2, varscan2
- AMOTL2 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 200/576 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs375446213; called by muse, varscan2
- ANK3 | c.7069G>A p.E2357K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV55047986; called by muse, mutect2, varscan2
- ANKRD11 | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV56373056; called by muse, mutect2, varscan2
- ANKRD11 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs555075240, COSV56373063; called by muse, mutect2, varscan2
- ANKRD29 | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV52427975; called by muse, varscan2
- ANKRD30A | c.1426G>A p.E476K (on ENST00000611781; = p.E420K on NM_052997.2) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as rs867286949, COSV64607688; called by muse, mutect2, varscan2
- ANKRD30A | c.2672C>T p.P891L (on ENST00000611781; = p.P835L on NM_052997.2) | Missense Mutation (SNP) | VAF 60/76 reads (79%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.927); catalogued as rs1475783959, COSV64622466; called by muse, mutect2, varscan2
- ANLN | c.2973C>T p.T991= | Splice Region (SNP) | VAF 12/23 reads (52%) | catalogued as rs182794031, COSV56079901; called by muse, mutect2, varscan2
- ANO1 | c.1151A>T p.K384M | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV60289925; called by mutect2, varscan2
- ANO3 | c.2231A>T p.Q744L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV56810119; called by muse, mutect2, varscan2
- AP4E1 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.03); catalogued as COSV55920488; called by muse, mutect2, varscan2
- AP4S1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs568176223, COSV53555732; called by muse, mutect2, varscan2
- APH1A | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52530119; called by muse, mutect2, varscan2
- APPBP2 | c.1207C>T p.L403F | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); catalogued as COSV50030008; called by muse, mutect2, varscan2
- ARHGAP31 | c.3989C>T p.S1330F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV51799795; called by muse, mutect2, varscan2
- ARHGAP45 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 22/101 reads (22%) | catalogued as COSV57436822; called by muse, mutect2, varscan2
- ARHGEF5 | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV50220613; called by muse, mutect2
- ARID5B | c.1267del p.R423Gfs*56 | Frame Shift Del (DEL) | VAF 62/68 reads (91%) | catalogued as COSV54429013; called by mutect2, pindel*, varscan2
- ARID5B | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV54430683; called by muse, mutect2, varscan2
- ARL5B | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0.201); catalogued as rs1273232468, COSV66011731; called by muse, mutect2, varscan2
- ARNTL2 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.225); catalogued as COSV99668199; called by muse, mutect2, varscan2
- ARPP21 | c.2062G>A p.G688R | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV51798213; called by muse, mutect2, varscan2
- ARPP21 | c.2063G>A p.G688E | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs762836472, COSV99491081; called by muse, mutect2, varscan2
- ARSF | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV63840443; called by muse, mutect2, varscan2
- ARSJ | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1276080356, COSV59540085; called by muse, varscan2
- ARSL | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.042); catalogued as rs750673516, COSV66966069; called by muse, mutect2, varscan2
- ASH1L | c.5855C>T p.P1952L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as COSV64214371; called by muse, mutect2, varscan2
- ASTN1 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs760442147, COSV56061330; called by muse, mutect2, varscan2
- ASTN1 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.898); catalogued as rs1485620000, COSV56081808; called by mutect2, varscan2
- ASTN1 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56087424; called by muse, mutect2, varscan2
- ASXL2 | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs367562789; called by muse, mutect2, varscan2
- ATF6B | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 112/408 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV64322892; called by muse, varscan2
- ATF7 | c.925C>T p.Q309* (on ENST00000548446 / NM_001366555.2; = p.Q298* on NM_006856.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | catalogued as COSV60646676; called by muse, varscan2
- ATG16L2 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 141/581 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs761722652, COSV58362418; called by muse, mutect2, varscan2
- ATG2A | c.1525C>G p.R509G | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV65969019; called by muse, mutect2, varscan2
- ATL3 | c.566T>A p.F189Y | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60298449; called by muse, mutect2, varscan2
- ATP13A2 | c.418G>A p.G140S | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV58704250; called by muse, mutect2, varscan2
- ATP13A5 | c.3473G>A p.R1158K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as COSV53230231; called by muse, mutect2, varscan2
- ATP1A2 | c.3028C>T p.P1010S | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV63405801; called by muse, mutect2, varscan2
- ATP2A1 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100706809, COSV62870850, COSV62871192; called by muse, mutect2, varscan2
- ATP2A2 | c.2009T>G p.L670R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57876423; called by muse, mutect2, varscan2
- ATP6AP1 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 73/116 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63895623; called by muse, mutect2, varscan2
- ATP6V0A4 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV59481011; called by muse, mutect2, varscan2
- ATP6V1B2 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV52355487; called by muse, mutect2, varscan2
- ATP8B1 | c.2122G>C p.D708H | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52180719; called by muse, mutect2, varscan2
- ATP8B4 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV52723256; called by muse, mutect2, varscan2
- ATP9A | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV58772610; called by muse, mutect2, varscan2
- ATRNL1 | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.339); catalogued as COSV58117175; called by mutect2, varscan2
- ATRNL1 | c.3151C>T p.P1051S | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58117182; called by muse, mutect2, varscan2
- ATRX | c.6178G>A p.E2060K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as COSV64874506, COSV64884420; called by muse, mutect2, varscan2
- AUTS2 | c.2402C>T p.P801L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61432185; called by muse, mutect2, varscan2
- AUTS2 | c.3632C>T p.T1211I | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV61432192; called by muse, mutect2, varscan2
- B4GALNT2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs147132109, COSV100302810; called by muse, mutect2, varscan2
- B4GALT3 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.031); catalogued as rs770859442, COSV100157990; called by muse, varscan2
- BAIAP2 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs776985011, COSV58373657; called by muse, mutect2, varscan2
- BARX2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs778608962, COSV55652607; called by mutect2, varscan2
- BARX2 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769021373, COSV55650354; called by muse, varscan2
- BAZ1A | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV62408864; called by muse, mutect2
- BCL9L | c.3665C>T p.S1222F | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV52689573; called by muse, mutect2, varscan2
- BCO1 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV50734463; called by muse, mutect2, varscan2
- BDKRB1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 153/339 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV53706009, COSV53707383; called by muse, mutect2, varscan2
- BECN1 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59312186; called by muse, mutect2, varscan2
- BEST3 | c.1940A>G p.E647G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as COSV58306116; called by muse, mutect2, varscan2
- BEX5 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 71/119 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV61328355; called by muse, mutect2, varscan2
- BICD2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV100794405; called by muse, mutect2
- BIN2 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as rs1216225639, COSV57208337; called by muse, mutect2, varscan2
- BLK | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs538418869, COSV52050491; called by muse, varscan2
- BNC1 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs200106261, COSV61759322; called by muse, mutect2, varscan2
- BPI | c.1308G>A p.M436I (on ENST00000262865; = p.M432I on NM_001725.3) | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.072); catalogued as COSV53408714; called by muse, mutect2, varscan2
- BRD8 | c.2617C>T p.H873Y | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50171240; called by muse, mutect2, varscan2
- BRD9 | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV60250524; called by muse, mutect2, varscan2
- BRINP3 | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66542667; called by muse, mutect2, varscan2
- BRIP1 | c.2035C>T p.L679F | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555601056, COSV52009829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTBD17 | c.1354T>A p.S452T | Missense Mutation (SNP) | VAF 77/126 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64730844; called by mutect2, varscan2
- BTLA | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.089); catalogued as COSV57940851; called by muse, varscan2
- BTRC | c.1048C>T p.Q350* (on ENST00000370187 / NM_033637.4; = p.Q314* on NM_003939.5) | Nonsense Mutation (SNP) | VAF 37/96 reads (39%) | catalogued as COSV100927952; called by muse, mutect2, varscan2
- C14orf93 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as COSV54442745; called by muse, mutect2, varscan2
- C1QC | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 40/41 reads (98%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as rs1557606334, COSV65889607; called by muse, mutect2, varscan2
- C1RL | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); catalogued as rs1258353937, COSV56926883; called by muse, mutect2
- C3 | c.2609C>T p.P870L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV55582176; called by muse, mutect2, varscan2
- C3 | c.1064T>A p.I355N | Missense Mutation (SNP) | VAF 146/352 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55582188; called by muse, mutect2, varscan2
- C3orf20 | c.1459G>A p.V487I | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.232); catalogued as rs148561738; called by muse, mutect2, varscan2
- C5AR1 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 77/124 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.276); catalogued as rs751023439, COSV61892620; called by muse, mutect2, varscan2
- C6orf58 | c.98G>A p.W33* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV61667437; called by muse, mutect2, varscan2
- C7 | c.1805G>A p.G602E | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57481866; called by muse, mutect2, varscan2
- C9orf135 | c.450-1G>A p.X150_splice | Splice Site (SNP) | VAF 4/23 reads (17%) | catalogued as COSV65876943; called by muse, mutect2
- CA2 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53408509; called by muse, mutect2, varscan2
- CAB39L | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 112/400 reads (28%) | catalogued as COSV61717093; called by muse, mutect2, varscan2
- CACNA1D | c.1835C>T p.P612L (on ENST00000350061 / NM_001128840.3; = p.P632L on NM_000720.4) | Missense Mutation (SNP) | VAF 113/383 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55466320; called by muse, mutect2, varscan2
- CACNA2D4 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV54961992; called by muse, mutect2, varscan2
- CACNB1 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60000493; called by muse, mutect2, varscan2
- CACNB2 | c.1843G>A p.E615K (on ENST00000324631 / NM_201596.3; = p.E560K on NM_000724.4) | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.524); catalogued as COSV56649421; called by muse, mutect2, varscan2
- CACTIN | c.645C>T p.A215= | Splice Region (SNP) | VAF 18/59 reads (31%) | catalogued as COSV50272620, COSV50274075; called by muse, mutect2, varscan2
- CAD | c.4849C>G p.R1617G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as COSV53032398; called by muse, mutect2
- CADPS | c.3477G>A p.E1159= | Splice Region (SNP) | VAF 4/25 reads (16%) | catalogued as rs779428191; called by mutect2, varscan2
- CALD1 | c.2068A>G p.K690E (on ENST00000361675 / NM_033138.4; = p.K435E on NM_004342.7) | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV62654781; called by muse, mutect2, varscan2
- CALN1 | c.160G>A p.G54S (on ENST00000329008 / NM_001017440.3; = p.G96S on NM_031468.4) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100210060; called by muse, mutect2, varscan2
- CAMKK2 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 127/385 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV61216469; called by muse, mutect2, varscan2
- CAMSAP2 | c.2945C>T p.S982F (on ENST00000236925 / NM_001297707.2; = p.S971F on NM_203459.3) | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as COSV52678368; called by muse, mutect2, varscan2
- CANX | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56007163; called by muse, mutect2, varscan2
- CAPN11 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 58/89 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs1211849622, COSV67239653; called by muse, mutect2, varscan2
- CAPZA3 | c.271T>G p.S91A | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56859354; called by muse, mutect2, varscan2
- CARM1 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV53405138; called by muse, mutect2, varscan2
- CARS1 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 110/173 reads (64%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as COSV53461490; called by muse, mutect2, varscan2
- CATIP | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs921668962, COSV56824582; called by muse, mutect2, varscan2
- CAVIN2 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 199/320 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV58426092; called by muse, mutect2, varscan2
- CCDC116 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.842); catalogued as rs138868031; called by muse, mutect2, varscan2
- CCDC181 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63158259; called by muse, mutect2, varscan2
- CCHCR1 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66161735; called by muse, mutect2
- CCNJL | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs755233695, COSV57446204; called by muse, mutect2, varscan2
- CCT8L2 | c.1657C>T p.L553F | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as rs1447379647, COSV100743220; called by muse, mutect2, varscan2
- CD163 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775798, COSV100776217; called by muse, mutect2, varscan2
- CD163L1 | c.2135G>A p.G712E | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs867073039, COSV58010539; called by muse, mutect2, varscan2
- CD2 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65643353; called by muse, mutect2, varscan2
- CD300E | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.589); catalogued as COSV60790231; called by muse, varscan2
- CD300E | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV100151261; called by muse, varscan2
- CD33 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.772); catalogued as COSV51805235, COSV99220052; called by muse, mutect2, varscan2
- CD84 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as COSV100245840, COSV60867252; called by muse, mutect2, varscan2
- CD86 | c.22G>A p.G8R (on ENST00000330540 / NM_175862.5; = p.G2R on NM_006889.4) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.406); catalogued as rs1234591391, COSV52610672; called by muse, mutect2, varscan2
- CDC25B | c.1702C>T p.R568W (on ENST00000245960 / NM_021873.3; = p.R554W on NM_004358.4) | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746499541, COSV55659925; called by mutect2, varscan2
- CDC42BPB | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63477002; called by muse, mutect2, varscan2
- CDCA7L | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as COSV60984378; called by muse, mutect2, varscan2
- CDCP1 | c.600G>A p.W200* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99944421; called by muse, mutect2, varscan2
- CDCP1 | c.599G>A p.W200* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV56108321; called by mutect2, varscan2
- CDH18 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.219); catalogued as rs866875588, COSV56959856; called by muse, varscan2
- CDHR1 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100259473; called by muse, mutect2, varscan2
- CDKN1B | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 88/131 reads (67%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.958); catalogued as rs375297371, COSV99964052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDRT15 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); catalogued as COSV69755815; called by muse, mutect2, varscan2
- CDS2 | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV66897886; called by muse, mutect2, varscan2
- CEACAM21 | c.805G>A p.D269N (on ENST00000401445 / NM_001098506.4; = p.D268N on NM_033543.6) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs374431132; called by muse, mutect2, varscan2
- CECR2 | c.2582G>A p.R861Q (on ENST00000342247 / NM_001290047.2; = p.R678Q on NM_001290046.1) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1390347431, COSV52849059; called by mutect2, varscan2
- CECR2 | c.3752C>T p.P1251L (on ENST00000342247 / NM_001290047.2; = p.P1067L on NM_001290046.1) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV52849080, COSV99377390; called by muse, mutect2, varscan2
- CENPP | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 64/95 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV55336440; called by muse, mutect2, varscan2
- CEP112 | c.1548A>C p.L516F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as COSV67145092; called by muse, mutect2, varscan2
- CEP128 | c.2618A>C p.K873T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55391980; called by muse, mutect2
- CERKL | c.1649G>A p.G550E (on ENST00000339098 / NM_001030311.2; = p.G524E on NM_201548.5) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1377681766, COSV59203862; called by muse, varscan2
- CES3 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV57593256; called by muse, mutect2, varscan2
- CES4A | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58658410; called by muse, mutect2, varscan2
- CES5A | c.1163A>C p.E388A | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV51871165; called by muse, mutect2, varscan2
- CFAP100 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100729154, COSV61504760; called by muse, varscan2
- CFAP100 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV61504766; called by muse, varscan2
- CFAP206 | c.1419G>C p.K473N | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as COSV51537514; called by muse, mutect2, varscan2
- CFAP206 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1405987812, COSV65806689; called by mutect2, varscan2
- CFAP251 | c.2063C>T p.P688L | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV56616344; called by muse, mutect2, varscan2
- CFAP47 | c.1855C>T p.H619Y | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV52892455, COSV99934812; called by mutect2, varscan2
- CFAP57 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV65265942; called by muse, mutect2, varscan2
- CFAP97 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1350019837, COSV57110339; called by muse, mutect2, varscan2
- CFHR2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.545); catalogued as COSV66381707; called by muse, mutect2, varscan2
- CFHR3 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100807876; called by mutect2, varscan2
- CFTR | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM108945; called by muse, mutect2
- CHD1L | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV63615488; called by muse, mutect2, varscan2
- CHD8 | c.3982G>A p.E1328K (on ENST00000646647 / NM_001170629.2; = p.E1049K on NM_020920.4) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63218829; called by muse, varscan2
- CHIA | c.1331G>A p.R444K (on ENST00000343320; = p.R336K on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58478559; called by muse, mutect2, varscan2
- CHRNA1 | c.1127G>A p.R376K (on ENST00000261007 / NM_001039523.3; = p.R351K on NM_000079.4) | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); catalogued as COSV53681778, COSV53683614; called by muse, mutect2, varscan2
- CHST7 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV52101404; called by muse, mutect2, varscan2
- CHST7 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs374354748, COSV52101415; called by muse, mutect2, varscan2
- CIART | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV51746275; called by muse, mutect2, varscan2
- CILP2 | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.013); catalogued as rs1159491856, COSV99365338; called by muse, mutect2, varscan2
- CILP2 | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.269); catalogued as COSV99365339; called by muse, mutect2, varscan2
- CIT | c.3363C>T p.L1121= | Splice Region (SNP) | VAF 71/123 reads (58%) | catalogued as COSV55868588, COSV55884688, COSV99951307; called by muse, mutect2, varscan2
- CLCA4 | c.301-1G>A p.X101_splice | Splice Site (SNP) | VAF 19/22 reads (86%) | catalogued as rs1294628861, COSV55371423; called by muse, mutect2, varscan2
- CLCN1 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1255229981, COSV58374855; called by muse, mutect2, varscan2
- CLCN3 | c.889T>C p.S297P | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV61628727; called by muse, mutect2, varscan2
- CLDN18 | c.247A>G p.M83V | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51738254; called by muse, mutect2
- CLGN | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57776679; called by muse, mutect2, varscan2
- CLIP4 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as rs1275578729, COSV60751937; called by muse, mutect2
- CLVS1 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs867676093, COSV57983759, COSV57984678; called by muse, varscan2
- CMYA5 | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as rs768094007, COSV71409878; called by mutect2, varscan2
- CNGA4 | c.63G>A p.R21= | Splice Region (SNP) | VAF 80/310 reads (26%) | catalogued as rs1442671464, COSV56410229; called by muse, mutect2, varscan2
- CNTNAP2 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1378450832, COSV62265212, COSV62274183; called by muse, mutect2, varscan2
- CNTNAP2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV62143246; called by mutect2, varscan2
- CNTNAP2 | c.3667C>T p.P1223S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.391); catalogued as COSV62265220; called by muse, mutect2, varscan2
- CNTNAP5 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as rs1447158750, COSV70472787; called by mutect2, varscan2
- COL11A1 | c.4630C>T p.Q1544* | Nonsense Mutation (SNP) | VAF 19/34 reads (56%) | catalogued as COSV62199386; called by muse, mutect2, varscan2
- COL11A1 | c.3833G>A p.R1278K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.952); catalogued as COSV62173704, COSV62182589; called by muse, mutect2, varscan2
- COL14A1 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52870206; called by muse, mutect2, varscan2
- COL22A1 | c.4531C>T p.P1511S | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.401); catalogued as COSV57362810; called by muse, mutect2, varscan2
- COL27A1 | c.4624C>T p.L1542F | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.985); catalogued as COSV61931157; called by muse, mutect2, varscan2
- COL28A1 | c.1682A>T p.N561I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); catalogued as COSV68085079, COSV68085081; called by muse, mutect2, varscan2
- COL3A1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.328); catalogued as rs187907868, COSV58584690, COSV58597018; called by muse, mutect2, varscan2
- COL3A1 | c.2296C>T p.P766S | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV58597358; called by muse, mutect2, varscan2
- COL4A4 | c.3115G>A p.G1039R | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1245186753, COSV61637119; called by muse, mutect2, varscan2
- COL4A5 | c.3656C>T p.P1219L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV60373065; called by muse, mutect2, varscan2
- COL4A6 | c.2788G>A p.G930R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57879563; called by muse, mutect2, varscan2
- COL6A2 | c.1573G>A p.G525R | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56017161; called by muse, mutect2
- COL6A3 | c.4481G>A p.R1494K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55112229; called by muse, varscan2
- COL7A1 | c.5440C>T p.R1814C | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778035441, CM074759, COSV60402265; called by muse, mutect2, varscan2
- CPLX4 | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs986597829, COSV55313008; called by mutect2, varscan2
- CPN2 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs770853665, COSV60469923; called by muse, mutect2, varscan2
- CPN2 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV60472220; called by muse, mutect2, varscan2
- CPS1 | c.221A>T p.N74I | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV51810882; called by muse, mutect2, varscan2
- CRACD | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0.073); catalogued as rs1317056942, COSV51732555; called by muse, mutect2, varscan2
- CRB1 | c.1942A>G p.I648V | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.173); catalogued as COSV66334289; called by muse, mutect2, varscan2
- CREB3L1 | c.1319G>A p.S440N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs1430927805, COSV55833394; called by mutect2, varscan2
- CREBRF | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1437321060, COSV51636751; called by mutect2, varscan2
- CRX | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.553); catalogued as rs559042370, COSV55759881; called by muse, mutect2, varscan2
- CSF3 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.051); catalogued as COSV56642119; called by muse, mutect2, varscan2
- CSMD1 | c.7949A>G p.N2650S (on ENST00000520002; = p.N2649S on NM_033225.6) | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV59390127; called by muse, mutect2, varscan2
- CSMD1 | c.5471G>A p.G1824E (on ENST00000520002; = p.G1823E on NM_033225.6) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV59390149; called by muse, mutect2, varscan2
- CSMD3 | c.8810G>A p.G2937E (on ENST00000297405 / NM_001363185.1; = p.G2768E on NM_052900.3) | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52332589; called by muse, mutect2, varscan2
- CSMD3 | c.5921G>A p.G1974E (on ENST00000297405 / NM_001363185.1; = p.G1870E on NM_052900.3) | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV52332608; called by muse, mutect2, varscan2
- CSMD3 | c.3886-1G>A p.X1296_splice (on ENST00000297405 / NM_001363185.1; = p.X1192_splice on NM_052900.3) | Splice Site (SNP) | VAF 4/8 reads (50%) | catalogued as COSV52332628, COSV99033803; called by muse, mutect2
- CSMD3 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 64/360 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV52332654; called by muse, varscan2
- CTAGE6 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs778979165, COSV69919016; called by muse, mutect2, varscan2
- CTDSP2 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 79/121 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1479804428, COSV66079701; called by muse, mutect2, varscan2
- CUL4B | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV60691469; called by muse, mutect2, varscan2
- CUZD1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59028923; called by muse, mutect2, varscan2
- CXCR2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1298311873, COSV59279763; called by muse, mutect2, varscan2
- CYBB | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV66086466; called by muse, mutect2, varscan2
- CYP11B2 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.481); catalogued as COSV100011490; called by muse, mutect2, varscan2
- CYP3A7 | c.670+1G>A p.X224_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as COSV60483578; called by muse, mutect2, varscan2
- CYP46A1 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55896867; called by muse, mutect2, varscan2
- CYP4F12 | c.1361C>A p.S454* | Nonsense Mutation (SNP) | VAF 42/200 reads (21%) | catalogued as rs778560842, COSV61176942; called by mutect2, varscan2
- CYP4F3 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 102/217 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs964959320, COSV55407391; called by muse, mutect2, varscan2
- CYP8B1 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV60227788; called by muse, mutect2, varscan2
- CYTH4 | c.60G>C p.Q20H | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV50636280; called by muse, mutect2, varscan2
- DAW1 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV59369562; called by mutect2, varscan2
- DCAF11 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 95/356 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58110874; called by muse, mutect2, varscan2
- DCAF12L2 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63580369; called by mutect2, varscan2
- DCAF12L2 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63584356; called by muse, mutect2, varscan2
- DCAF12L2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.454); catalogued as rs767452980, COSV63580230, COSV63583864; called by muse, varscan2
- DCAF13 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.861); catalogued as COSV52574791; called by muse, mutect2, varscan2
- DCHS1 | c.194G>A p.S65N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs1483047083, COSV55043518; called by muse, mutect2, varscan2
- DCN | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50008499; called by muse, mutect2, varscan2
- DCTN2 | c.1187T>C p.M396T (on ENST00000548249 / NM_001261413.2; = p.M401T on NM_006400.4) | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV63076616; called by muse, mutect2, varscan2
- DCUN1D5 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs774048924, COSV52783895; called by muse, mutect2, varscan2
- DDX10 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 70/108 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0.247); catalogued as rs147675016; called by muse, mutect2, varscan2
- DDX54 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs919120286, COSV58374848; called by mutect2, varscan2
- DEF6 | c.1765G>A p.G589R | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV57355459; called by muse, mutect2, varscan2
- DENND5B | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100172086, COSV60908914; called by muse, mutect2, varscan2
- DEPDC5 | c.3626C>T p.P1209L (on ENST00000400246; = p.P1278L on NM_014662.5) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1569186377, COSV56711894; called by muse, mutect2, varscan2
- DGCR6L | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs375434608; called by muse, varscan2
- DHX29 | c.3935C>T p.S1312F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV99287801; called by muse, mutect2, varscan2
- DHX40 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs200066612, COSV52066666; called by mutect2, varscan2
- DHX9 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); catalogued as COSV62362503; called by mutect2, varscan2
- DIAPH1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.874); catalogued as COSV53889199; called by muse, mutect2, varscan2
- DIDO1 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 92/178 reads (52%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs759076690, COSV56634744; called by muse, mutect2, varscan2
- DIP2A | c.3845C>T p.A1282V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59487851; called by muse, mutect2, varscan2
- DIPK2B | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.234); catalogued as COSV101211724; called by muse, mutect2, varscan2
- DISP3 | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1473781398, COSV53838486; called by muse, mutect2, varscan2
- DLG5 | c.5099C>T p.S1700F | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64947794, COSV64950196; called by muse, mutect2, varscan2
- DMD | c.3600G>A p.M1200I | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV63795893; called by mutect2, varscan2
- DMD | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373475448, COSV55904302; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMD | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM165342, COSV55904326; called by muse, mutect2, varscan2
- DMXL2 | c.8750C>T p.S2917L | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV51852647; called by muse, mutect2, varscan2
- DNAH11 | c.2282G>A p.G761E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as COSV60977781; called by muse, mutect2, varscan2
- DNAH11 | c.8662C>T p.Q2888* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as rs964089960, COSV60984355; called by muse, mutect2, varscan2
- DNAH14 | c.548C>T p.P183L (on ENST00000445597; = p.P6L on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs924333528, COSV100836005; called by muse, mutect2, varscan2
- DNAH17 | c.11335G>A p.A3779T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV67761825; called by muse, mutect2, varscan2
- DNAH17 | c.10936G>A p.E3646K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as rs143100405; called by mutect2, varscan2
- DNAH17 | c.1258T>C p.F420L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV67761832; called by muse, varscan2
- DNAH2 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 59/100 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.34); catalogued as COSV50021327; called by muse, mutect2, varscan2
- DNAH3 | c.10525C>T p.Q3509* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV54555511; called by muse, mutect2, varscan2
- DNAH3 | c.7715C>T p.A2572V | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV54555532; called by muse, mutect2, varscan2
- DNAH3 | c.5873C>T p.S1958F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV54554311; called by muse, mutect2, varscan2
- DNAH3 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV54555565; called by mutect2, varscan2
- DNAH5 | c.1558A>G p.K520E | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV54255025; called by muse, mutect2, varscan2
- DNAH7 | c.8435C>T p.P2812L | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56788841; called by muse, mutect2, varscan2
- DNAH7 | c.7392T>A p.H2464Q | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV56771555, COSV56788871; called by muse, mutect2, varscan2
- DNAH7 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV56762530; called by mutect2, varscan2
- DNAH7 | c.1843C>T p.Q615* | Nonsense Mutation (SNP) | VAF 12/18 reads (67%) | catalogued as rs1268955453, COSV56752202; called by mutect2, varscan2
- DNAH8 | c.7039C>T p.H2347Y | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV59483451; called by mutect2, varscan2
- DNAH8 | c.11833G>A p.E3945K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV59483179; called by muse, mutect2, varscan2
- DNAH9 | c.2680G>A p.G894R | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV52350960; called by muse, mutect2, varscan2
- DNAH9 | c.4942G>A p.E1648K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99307866; called by muse, mutect2, varscan2
- DNAH9 | c.7234C>T p.P2412S | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52350008; called by muse, mutect2, varscan2
- DNAJA3 | c.808G>T p.V270L | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as COSV52164340; called by muse, mutect2, varscan2
- DNAJB6 | c.217T>A p.L73I | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV51100953; called by muse, mutect2, varscan2
- DNHD1 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs752485929, COSV54443910; called by muse, mutect2, varscan2
- DNMT1 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 147/327 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV61584260; called by muse, mutect2, varscan2
- DOCK10 | c.6088G>A p.E2030K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV51346817, COSV51429063; called by mutect2, varscan2
- DOCK10 | c.3254C>T p.S1085F | Missense Mutation (SNP) | VAF 66/117 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.352); catalogued as COSV51417531; called by muse, mutect2, varscan2
- DOCK5 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52412398; called by mutect2, varscan2
- DOT1L | c.2495C>T p.P832L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); catalogued as COSV67113745; called by muse, mutect2, varscan2
- DPYD | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as rs1411354209, COSV64616278; called by mutect2, varscan2
- DPYSL3 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV58331496; called by muse, mutect2, varscan2
- DRC3 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs267604763, COSV58266873; called by mutect2, varscan2
- DSC1 | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 76/118 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57152144; called by muse, mutect2, varscan2
- DSCAM | c.2755G>A p.D919N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101261371, COSV68033183; called by muse, mutect2, varscan2
- DSCAM | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV68037390; called by muse, mutect2, varscan2
- DSG3 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57130017, COSV57130094; called by mutect2, varscan2
- DST | c.14270A>G p.N4757S (on ENST00000361203 / NM_001374722.1; = p.N2345S on NM_015548.5) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV55042694; called by muse, mutect2, varscan2
- DTX1 | c.1603C>T p.H535Y | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.076); catalogued as COSV55660144; called by muse, mutect2, varscan2
- DTX3 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV54091092; called by muse, mutect2, varscan2
- DUOX2 | c.1947G>A p.A649= | Splice Region (SNP) | VAF 16/74 reads (22%) | catalogued as rs549920987, COSV66535008; called by mutect2, varscan2
- DUSP12 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 104/255 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63411639, COSV63411716; called by muse, mutect2, varscan2
- DUSP9 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 218/402 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61438136, COSV61438538; called by muse, mutect2, varscan2
- DYSF | c.4880T>C p.F1627S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs1553410562, COSV50613761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EDC4 | c.2056C>T p.P686S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.063); catalogued as COSV59304053; called by muse, mutect2, varscan2
- EDEM3 | c.1418T>C p.L473S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1362485571, COSV58928364; called by muse, mutect2, varscan2
- EEPD1 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs1316498632, COSV54203608; called by muse, mutect2
- EGFR | c.3025G>A p.D1009N | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as rs148019583, COSV51864136; called by muse, varscan2
- EIF3A | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs535803217, COSV100974742, COSV100974880; called by muse, mutect2, varscan2
- EIF3A | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV64961439; called by muse, mutect2, varscan2
- EIF4G3 | c.3107A>G p.N1036S | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV51695230; called by muse, varscan2
- ELK1 | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV55954776; called by muse, mutect2, varscan2
- ELN | c.1622G>C p.R541P | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.395); catalogued as COSV52716317; called by muse, mutect2, varscan2
- EML1 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs746895186, COSV51753694; called by muse, mutect2, varscan2
- EML5 | c.1526A>T p.N509I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.477); catalogued as COSV61352253; called by mutect2, varscan2
- EML5 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 165/340 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as rs773834442, COSV61352259; called by muse, mutect2, varscan2
- EML5 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 127/256 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs763457989, COSV61344205; called by muse, mutect2, varscan2
- ENAM | c.927G>A p.W309* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV68537113; called by muse, mutect2, varscan2
- ENC1 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs907154987, COSV56631482; called by muse, mutect2, varscan2
- ENPP7 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 23/73 reads (32%) | catalogued as COSV60386163; called by muse, mutect2, varscan2
- ENTHD1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs774070537, COSV57325598; called by mutect2, varscan2
- EP300 | c.5947G>A p.G1983R | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54346583; called by muse, mutect2, varscan2
- EPB41L2 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs1287860575, COSV61359422; called by muse, mutect2, varscan2
- EPG5 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV56353432; called by muse, mutect2, varscan2
- EPHA10 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60404472; called by muse, mutect2, varscan2
- EPHA3 | c.2236G>A p.D746N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60729666; called by mutect2, varscan2
- EPPIN | c.155G>A p.R52K | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.079); catalogued as COSV60549628; called by muse, varscan2
- ERBB4 | c.2974C>T p.R992C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs143134749; called by muse, mutect2, varscan2
- ERCC4 | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100319179; called by muse, mutect2, varscan2
- ERCC6L | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57822544; called by muse, mutect2, varscan2
- ERN2 | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 81/129 reads (63%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1400975601, COSV56838301; called by muse, mutect2, varscan2
- ERO1B | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51595175; called by muse, mutect2, varscan2
- ERVW-1 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV71259635; called by muse, mutect2, varscan2
- ESPNL | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV58038590; called by muse, mutect2, varscan2
- ESX1 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 96/277 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs1223242468, COSV65425275; called by muse, mutect2, varscan2
- ETFBKMT | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55673283; called by muse, mutect2, varscan2
- F10 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 69/117 reads (59%) | SIFT tolerated (0.53); PolyPhen benign (0.034); catalogued as COSV65023243; called by muse, mutect2, varscan2
- F2RL2 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV56971385; called by muse, mutect2, varscan2
- F8 | c.5104G>A p.D1702N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV64279201; called by muse, mutect2, varscan2
- F8 | c.3298A>G p.K1100E | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as CM055166, COSV64279209; called by muse, mutect2, varscan2
- F9 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD035541, CM940415, COSV54378564; called by muse, mutect2, varscan2
- FAM135B | c.1469A>C p.N490T | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV52755810; called by muse, mutect2, varscan2
- FAM32A | c.271-1G>A p.X91_splice | Splice Site (SNP) | VAF 43/104 reads (41%) | catalogued as COSV54624771, COSV99655355; called by muse, mutect2, varscan2
- FAM32A | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV54624751; called by muse, mutect2, varscan2
- FAM47A | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.104); catalogued as COSV60496872, COSV60500088; called by muse, varscan2
- FAM9A | c.373+1G>A p.X125_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as COSV66813796; called by muse, mutect2
- FAM9A | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.329); catalogued as COSV101121388; called by muse, mutect2, varscan2
- FARS2 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV51176602; called by mutect2, varscan2
- FAT1 | c.7789C>T p.R2597* | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as rs777631605, COSV71672084; called by muse, mutect2, varscan2
- FAT1 | c.4694C>T p.S1565F | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as COSV71676189; called by muse, mutect2, varscan2
- FAT4 | c.5081C>T p.A1694V | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV67901524; called by muse, mutect2, varscan2
- FBLN5 | c.747C>G p.D249E | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV50904377, COSV50906475; called by muse, mutect2, varscan2
- FBLN7 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV55615449, COSV55616179; called by muse, mutect2, varscan2
- FBXL7 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.461); catalogued as COSV61653895; called by muse, mutect2, varscan2
- FBXO47 | c.1220A>T p.E407V | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV65242946; called by muse, mutect2, varscan2
- FBXW10 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100111848; called by mutect2, varscan2
- FCAR | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV62032064; called by muse, mutect2, varscan2
- FCGBP | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs1449362947; called by muse, mutect2, varscan2
- FCHSD2 | c.1046T>G p.L349R | Missense Mutation (SNP) | VAF 172/566 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV60815146; called by muse, mutect2, varscan2
- FEM1A | c.1924C>T p.L642F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54165023; called by muse, mutect2, varscan2
- FFAR4 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 147/163 reads (90%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV65160863; called by muse, mutect2, varscan2
- FGF12 | c.415-1G>A p.X139_splice (on ENST00000454309 / NM_021032.5; = p.X77_splice on NM_004113.6) | Splice Site (SNP) | VAF 14/43 reads (33%) | catalogued as COSV53190831; called by muse, mutect2
- FGF17 | c.360C>T p.P120= | Splice Region (SNP) | VAF 8/62 reads (13%) | catalogued as rs1306787277, COSV63925918; called by muse, mutect2
- FGFR2 | c.2166G>A p.M722I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60661095; called by muse, mutect2, varscan2
- FHL1 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV61782921; called by muse, mutect2, varscan2
- FIBIN | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); catalogued as COSV100590327, COSV59413665; called by muse, mutect2
- FLACC1 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV51860004; called by muse, mutect2, varscan2
- FLCN | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 124/212 reads (58%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs751478971, COSV53263716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG | c.6718G>A p.G2240R | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.661); catalogued as COSV64250621; called by muse, mutect2, varscan2
- FLG | c.3770C>T p.S1257L | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.379); catalogued as COSV64250626; called by muse, mutect2, varscan2
- FLG | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.345); catalogued as rs1553214189, COSV64250633; called by muse, varscan2
- FLG2 | c.4261G>T p.G1421* | Nonsense Mutation (SNP) | VAF 31/85 reads (36%) | catalogued as COSV101166326, COSV66168512, COSV66168911; called by mutect2, varscan2
- FLT1 | c.3949A>C p.K1317Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as COSV56744364; called by muse, mutect2, varscan2
- FLT4 | c.3076G>A p.E1026K | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56123977; called by muse, mutect2, varscan2
- FMN2 | c.4693C>T p.L1565F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); catalogued as rs775335880, COSV60456331; called by muse, mutect2, varscan2
- FMO4 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV63001997; called by muse, mutect2, varscan2
- FMO5 | c.1308G>A p.M436I | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); catalogued as COSV54211070; called by muse, mutect2, varscan2
- FN1 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 91/273 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1049782878, COSV60557957; called by muse, mutect2, varscan2
- FNDC1 | c.3773C>T p.P1258L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV51948565; called by muse, mutect2, varscan2
- FNDC5 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 47/51 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65106109; called by muse, mutect2, varscan2
- FNIP2 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.311); catalogued as COSV52446632; called by muse, mutect2, varscan2
- FOXL1 | c.907A>T p.S303C | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.436); catalogued as COSV57215434; called by muse, mutect2, varscan2
- FOXL2NB | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV57730937; called by muse, mutect2, varscan2
- FREM1 | c.3742G>A p.D1248N | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV66530892; called by muse, mutect2, varscan2
- FRG2B | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV71042772, COSV71044237; called by mutect2, varscan2
- FRY | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV66577175; called by muse, mutect2, varscan2
- FSCN3 | c.150G>A p.W50* | Nonsense Mutation (SNP) | VAF 26/101 reads (26%) | catalogued as COSV50002167; called by muse, mutect2, varscan2
- FYB1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV60941035; called by muse, mutect2, varscan2
- FYB2 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs868676186, COSV58582820, COSV58583406; called by muse, mutect2, varscan2
- FZR1 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV58052403; called by muse, mutect2, varscan2
- GABRA6 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760815978, COSV50896211, COSV99195380; called by muse, mutect2, varscan2
- GABRB3 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV54678496; called by muse, mutect2, varscan2
- GABRG3 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61535282; called by muse, varscan2
- GAD1 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV60153032, COSV60154077; called by muse, mutect2, varscan2
- GAD1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs775306074, COSV100713965, COSV60151622; called by muse, mutect2, varscan2
- GAGE10 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 131/585 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs1445940734, COSV68163635; called by muse, mutect2
- GAL3ST4 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 88/394 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100385654, COSV57588410; called by muse, mutect2, varscan2
- GALC | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99730749; called by mutect2, varscan2
- GALNS | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV51940832; called by muse, mutect2, varscan2
- GALNT15 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60220163; called by muse, mutect2, varscan2
- GALNT17 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773651456, COSV61160937; called by mutect2, varscan2
- GALNT7 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1250176489, COSV53933533; called by muse, mutect2, varscan2
- GAREM1 | c.1831C>T p.P611S (on ENST00000269209 / NM_001242409.2; = p.P610S on NM_022751.3) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.162); catalogued as COSV52515198; called by muse, mutect2, varscan2
- GBA3 | c.768A>T p.K256N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.287); catalogued as COSV72438806; called by muse, mutect2, varscan2
- GCN1 | c.7064C>T p.A2355V | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV56115386; called by muse, mutect2, varscan2
- GCNA | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV65468435; called by muse, varscan2
- GCOM1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV51099608; called by mutect2, varscan2
- GDPD1 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52385240; called by muse, mutect2, varscan2
- GDPD2 | c.1379G>A p.W460* | Nonsense Mutation (SNP) | VAF 58/182 reads (32%) | catalogued as COSV100978738; called by muse, varscan2
- GDPD2 | c.1380G>A p.W460* | Nonsense Mutation (SNP) | VAF 55/182 reads (30%) | catalogued as COSV65534499; called by muse, varscan2
- GEM | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52599399; called by muse, mutect2, varscan2
- GGN | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as COSV53057924, COSV53059204; called by muse, mutect2, varscan2
- GIMAP8 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56234400; called by muse, mutect2, varscan2
- GJA1 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.797); catalogued as COSV56999787; called by muse, mutect2, varscan2
- GJA8 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53789087; called by muse, mutect2
- GK2 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62628321; called by muse, mutect2, varscan2
- GK2 | c.341G>A p.W114* | Nonsense Mutation (SNP) | VAF 40/111 reads (36%) | catalogued as rs1019557636, COSV62628561; called by muse, mutect2, varscan2
- GLDN | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); catalogued as rs1445959242, COSV59092750; called by muse, mutect2, varscan2
- GLI2 | c.3899C>T p.P1300L (on ENST00000361492 / NM_001374353.1; = p.P1317L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV58052219; called by muse, mutect2
- GLI2 | c.4295G>A p.G1432D (on ENST00000361492 / NM_001374353.1; = p.G1449D on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58052228; called by muse, mutect2, varscan2
- GLRA3 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56870993; called by muse, mutect2, varscan2
- GLT6D1 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65628306, COSV65628607; called by muse, mutect2, varscan2
- GLYATL2 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as COSV54851694; called by muse, mutect2, varscan2
- GMPPB | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV57540326; called by mutect2, varscan2
- GNA11 | c.980A>G p.H327R | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50055205; called by muse, mutect2, varscan2
- GNAZ | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV50740741; called by muse, mutect2, varscan2
- GNGT2 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55930398; called by muse, mutect2, varscan2
- GOLGA4 | c.5177C>T p.S1726F | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.1); catalogued as COSV62711749; called by muse, varscan2
- GOLGB1 | c.6772G>A p.E2258K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61471744; called by mutect2, varscan2
- GP6 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100117821; called by mutect2, varscan2
- GP6 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767613010, COSV59978332; called by muse, mutect2, varscan2
- GPC3 | c.1555C>T p.Q519* | Nonsense Mutation (SNP) | VAF 22/63 reads (35%) | catalogued as COSV63672723; called by muse, mutect2, varscan2
- GPLD1 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.054); catalogued as rs1203901847, COSV57756256; called by muse, mutect2, varscan2
- GPR141 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57734250; called by muse, mutect2, varscan2
- GPR149 | c.1666G>A p.G556R | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101078843; called by muse, varscan2
- GPR17 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV55757317; called by muse, mutect2, varscan2
- GPR20 | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100897440, COSV66684249; called by mutect2, varscan2
- GPR50 | c.1093G>T p.V365F | Missense Mutation (SNP) | VAF 82/147 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV54443231; called by muse, mutect2, varscan2
- GPR61 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 59/68 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV63984594; called by muse, mutect2, varscan2
- GPSM1 | c.1916G>A p.R639K | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs782071451, COSV52518586; called by muse, mutect2, varscan2
- GRIPAP1 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781956837, COSV64552087; called by muse, mutect2, varscan2
- GRIPAP1 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as rs933063112, COSV100904429; called by muse, mutect2, varscan2
- GTF3C1 | c.5785C>T p.Q1929* | Nonsense Mutation (SNP) | VAF 54/152 reads (36%) | catalogued as COSV62245313; called by muse, varscan2
- GTF3C2 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV53128737, COSV53128960; called by muse, mutect2, varscan2
- GUCY2C | c.2907A>G p.I969M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV53796218; called by muse, mutect2, varscan2
- HAAO | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54313304; called by muse, mutect2, varscan2
- HBG2 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs151258456, COSV57963441; called by mutect2, varscan2
- HCN1 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.014); catalogued as COSV57509367; called by muse, mutect2, varscan2
- HDAC6 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV61930334; called by muse, mutect2, varscan2
- HDGFL2 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 93/199 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs543970158, COSV56683035; called by muse, mutect2, varscan2
- HDX | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 72/107 reads (67%) | SIFT tolerated (0.26); PolyPhen benign (0.265); catalogued as COSV52973294; called by muse, mutect2, varscan2
- HECTD1 | c.4790C>T p.P1597L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101237587; called by muse, mutect2, varscan2
- HECW2 | c.4409G>A p.G1470E | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53675762; called by muse, mutect2, varscan2
- HELZ2 | c.5012C>A p.A1671D (on ENST00000467148 / NM_001037335.2; = p.A1102D on NM_033405.3) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71295301, COSV71297081; called by muse, mutect2, varscan2
- HERC1 | c.8242C>T p.P2748S | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV71250488; called by muse, mutect2, varscan2
- HGS | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1203335350, COSV61270588; called by muse, varscan2
- HIRA | c.1967C>T p.S656F | Missense Mutation (SNP) | VAF 35/316 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV54277429; called by muse, mutect2, varscan2
- HIVEP1 | c.3704C>T p.P1235L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65105381; called by muse, mutect2, varscan2
- HIVEP3 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV56024528; called by muse, mutect2, varscan2
- HJURP | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV64979664; called by muse, mutect2, varscan2
- HK2 | c.2285C>T p.T762I | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV51880101; called by muse, mutect2, varscan2
- HLA-DRA | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as COSV66623158; called by muse, mutect2, varscan2
- HM13 | c.808+1G>A p.X270_splice | Splice Site (SNP) | VAF 16/89 reads (18%) | catalogued as COSV59439858; called by muse, mutect2, varscan2
- HMCN1 | c.5619C>G p.N1873K | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.567); catalogued as COSV54945272; called by muse, mutect2, varscan2
- HMGCLL1 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51440270; called by muse, mutect2, varscan2
- HNF1A | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 118/386 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1320041799, COSV57467495, COSV57468281; called by muse, mutect2, varscan2
- HOATZ | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV60442626; called by muse, varscan2
- HOMEZ | c.1429C>G p.R477G | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV62537915; called by muse, mutect2, varscan2
- HOXB1 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as rs780483178, COSV53317604, COSV53318834; called by muse, varscan2
- HPS4 | c.1753C>T p.H585Y | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61105321, COSV61106039; called by muse, mutect2, varscan2
- HRC | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs775263588, COSV53259136; called by muse, mutect2, varscan2
- HS3ST4 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58810580, COSV58832687; called by muse, mutect2, varscan2
- HS3ST4 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs766701419, COSV58805237; called by mutect2, varscan2
- HSPG2 | c.10054T>G p.F3352V | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV65934130; called by muse, varscan2
- HSPG2 | c.7604C>T p.P2535L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65977819; called by muse, mutect2, varscan2
- HTR3C | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.098); catalogued as COSV59177535; called by muse, mutect2, varscan2
- HTR7 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); catalogued as COSV53288699; called by mutect2, varscan2
- HUWE1 | c.11482G>T p.D3828Y | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV53365509; called by muse, mutect2, varscan2
- HUWE1 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 77/222 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1372033852, COSV53365532; called by muse, mutect2, varscan2
- HYDIN | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as COSV55500711; called by muse, mutect2, varscan2
- HYDIN | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV55500754; called by muse, mutect2, varscan2
- ICA1 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55584888; called by muse, mutect2, varscan2
- ICA1L | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 252/741 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64175425; called by muse, mutect2, varscan2
- ICE1 | c.3839A>C p.K1280T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV56833380; called by muse, mutect2, varscan2
- IFT172 | c.5075C>T p.P1692L | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV99275361; called by muse, mutect2, varscan2
- IGFBP1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV51875608; called by muse, mutect2, varscan2
- IGFBP2 | c.502A>G p.N168D | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV52081583; called by muse, mutect2, varscan2
- IGHM | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT tolerated (0.23); catalogued as rs369884599; called by muse, mutect2, varscan2
- IGHV3-43 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as rs763010736; called by muse, mutect2, varscan2
- IGSF10 | c.7597C>T p.R2533C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs776551400, COSV56373877; called by muse, mutect2, varscan2
- IGSF5 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.246); catalogued as COSV66029791; called by muse, mutect2, varscan2
- IL13RA1 | c.951T>G p.N317K | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0.109); catalogued as COSV65425221; called by muse, mutect2, varscan2
- IL16 | c.1390G>A p.G464R | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.523); catalogued as COSV100268360; called by muse, mutect2, varscan2
- IL16 | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.092); catalogued as rs1414975054, COSV57260394, COSV57260567; called by muse, mutect2, varscan2
- IL1RL1 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs867114006, COSV52119033; called by muse, mutect2, varscan2
- IL1RL2 | c.1458T>G p.I486M | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51819481; called by muse, mutect2, varscan2
- IL36B | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52084330; called by muse, mutect2, varscan2
- ILDR2 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.069); catalogued as COSV54835863; called by muse, mutect2, varscan2
- INPP5B | c.2893C>T p.R965* (on ENST00000373023; = p.R885* on NM_005540.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 49/121 reads (40%) | catalogued as rs375829441; called by muse, mutect2, varscan2
- INSRR | c.3790G>A p.E1264K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV100948249; called by muse, mutect2, varscan2
- INTS14 | c.1481C>T p.S494F (on ENST00000313182 / NM_001366360.2; = p.S415F on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV56013030; called by muse, mutect2, varscan2
- INTS6L | c.2371A>T p.K791* | Nonsense Mutation (SNP) | VAF 28/49 reads (57%) | catalogued as COSV66086590; called by mutect2, varscan2
- IPCEF1 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 80/193 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV54552034; called by muse, mutect2, varscan2
- IPO4 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 215/492 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99938383; called by muse, mutect2, varscan2
- IPO4 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 214/489 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV55780776; called by muse, mutect2, varscan2
- IQSEC2 | c.1882C>T p.P628S (on ENST00000642864 / NM_001111125.3; = p.P423S on NM_015075.2) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV64728335; called by muse, varscan2
- IQUB | c.1558T>G p.L520V | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV61243126; called by muse, mutect2, varscan2
- IRS4 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.221); catalogued as COSV64536179; called by muse, mutect2, varscan2
- ISX | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372031013; called by mutect2, varscan2
- ITGAM | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as COSV54943277; called by muse, mutect2, varscan2
- ITGAX | c.3145G>A p.G1049S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1448394651, COSV51652142; called by muse, mutect2, varscan2
- ITGB1 | c.1496A>T p.H499L | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV56487240; called by muse, mutect2, varscan2
- ITGBL1 | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV66012386; called by muse, mutect2, varscan2
- ITIH2 | c.2630G>A p.G877E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1030418074, COSV100623487; called by muse, mutect2, varscan2
- ITM2C | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs748800653, COSV58400389; called by muse, mutect2, varscan2
- ITPRID2 | c.1578T>C p.V526= | Splice Region (SNP) | VAF 58/100 reads (58%) | catalogued as COSV57472402; called by muse, mutect2, varscan2
- JAM2 | c.865-1G>A p.X289_splice | Splice Site (SNP) | VAF 32/34 reads (94%) | catalogued as COSV57260981; called by muse, mutect2, varscan2
- JARID2 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs371504573, COSV59199007; called by mutect2, varscan2
- JMJD7-PLA2G4B | c.881G>A p.S294N | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1222561731, COSV59828793; called by muse, mutect2, varscan2
- JUP | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV60280011; called by muse, mutect2, varscan2
- KANSL3 | c.2410C>T p.R804C (on ENST00000666923 / NM_001349262.2; = p.R778C on NM_001115016.3) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs368507889; called by muse, mutect2, varscan2
- KATNAL2 | c.861G>A p.W287* (on ENST00000356157 / NM_001353899.1; = p.W215* on NM_031303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs756265561, COSV55302949, COSV55309546; called by mutect2, varscan2
- KCNA6 | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 92/140 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV54978264; called by muse, mutect2, varscan2
- KCNB1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.688); catalogued as COSV65571078; called by muse, mutect2, varscan2
- KCNB1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.519); catalogued as COSV65571086; called by muse, mutect2, varscan2
- KCNB2 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV73048927, COSV73051668; called by muse, mutect2, varscan2
- KCNB2 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73050367; called by muse, mutect2, varscan2
- KCNB2 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as rs758944083, COSV73051961; called by muse, mutect2, varscan2
- KCNB2 | c.2546G>A p.G849D | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV73053197; called by muse, mutect2, varscan2
- KCND1 | c.1205T>C p.L402P | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54416201; called by muse, mutect2, varscan2
- KCND2 | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV58606216; called by muse, mutect2, varscan2
- KCNG4 | c.1115G>A p.G372D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57583609; called by muse, mutect2, varscan2
- KCNG4 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV57585892; called by muse, mutect2, varscan2
- KCNH1 | c.1298A>T p.N433I (on ENST00000271751 / NM_172362.3; = p.N406I on NM_002238.4) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99662087; called by muse, mutect2, varscan2
- KCNH4 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV52916869; called by muse, mutect2, varscan2
- KCNH7 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs867811019, COSV59813621; called by muse, mutect2, varscan2
- KCNJ3 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54545520; called by muse, mutect2, varscan2
- KCNQ5 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs866886558, COSV59669652; called by mutect2, varscan2
- KCNS2 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54641302; called by muse, mutect2, varscan2
- KCNT1 | c.1210C>T p.P404S (on ENST00000488444; = p.P423S on NM_020822.3) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV53711957; called by muse, mutect2, varscan2
- KCNT2 | c.3214G>A p.E1072K | Missense Mutation (SNP) | VAF 89/193 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs867616993, COSV54079273, COSV99038344; called by muse, mutect2, varscan2
- KCTD8 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 67/123 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs549391615, COSV63588118; called by muse, mutect2, varscan2
- KDM3B | c.1087A>C p.N363H | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58695871; called by muse, mutect2, varscan2
- KDM5A | c.5047A>G p.M1683V | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs150903623, COSV66996660; called by muse, mutect2, varscan2
- KDM7A | c.2449C>T p.H817Y | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV50096894; called by mutect2, varscan2
- KIAA1210 | c.2950A>T p.K984* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV68180491; called by mutect2, varscan2
- KIAA1217 | c.3301G>A p.A1101T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV56824695; called by muse, mutect2, varscan2
- KIF21B | c.4836G>A p.W1612* (on ENST00000422435 / NM_001252100.2; = p.W1599* on NM_017596.4) | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as COSV100145330; called by muse, mutect2, varscan2
- KIF21B | c.4835G>A p.W1612* (on ENST00000422435 / NM_001252100.2; = p.W1599* on NM_017596.4) | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV100145332; called by mutect2, varscan2
- KIF26A | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329724416, COSV100181723; called by muse, mutect2, varscan2
- KIF27 | c.4100C>T p.S1367F | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV52831512; called by muse, mutect2, varscan2
- KLHL10 | c.1652C>T p.T551I | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV53174531, COSV53175231; called by muse, varscan2
- KLHL13 | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53245707; called by muse, mutect2, varscan2
- KLHL4 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.866); catalogued as COSV64142258; called by muse, mutect2
- KLK1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372142347, COSV56828894; called by muse, mutect2, varscan2
- KLK13 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147145797; called by muse, mutect2, varscan2
- KLK15 | c.752A>G p.E251G | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as COSV56828824; called by muse, mutect2, varscan2
- KLK15 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763136204, COSV100033077, COSV56826089; called by mutect2, varscan2
- KLRG1 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866842598, COSV56945227, COSV99868441; called by muse, mutect2
- KMT2C | c.12104C>T p.P4035L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51507813; called by muse, varscan2
- KMT2C | c.5455A>T p.M1819L | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV51507862; called by muse, mutect2, varscan2
- KNG1 | c.239A>T p.E80V | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs751510393, COSV53981375; called by mutect2, varscan2
- KRT32 | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV56787382; called by muse, mutect2, varscan2
- KRT37 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1210452310, COSV56660275; called by muse, mutect2, varscan2
- KRT71 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1161525255, COSV57289359; called by mutect2, varscan2
- KRT73 | c.1571C>T p.S524F | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.057); catalogued as COSV99988800, COSV99988951; called by muse, mutect2, varscan2
- KRTAP17-1 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | PolyPhen probably damaging (0.999); catalogued as COSV61972610; called by muse, mutect2, varscan2
- KRTAP26-1 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1434900475, COSV100860449, COSV62129034; called by muse, mutect2, varscan2
- KRTAP5-7 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as rs772783550, COSV68325337; called by muse, varscan2
- KSR1 | c.2021C>T p.S674L (on ENST00000644974 / NM_001367810.1; = p.S559L on NM_014238.2) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1421756754, COSV52029184, COSV99260697; called by mutect2, varscan2
- KSR2 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60365480; called by muse, mutect2, varscan2
- KTN1 | c.2081C>T p.S694L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as COSV68025868; called by muse, mutect2, varscan2
- L3MBTL2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV53435996; called by muse, mutect2, varscan2
- LAMA2 | c.4664G>A p.R1555K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as rs1314123853, COSV70356042; called by muse, mutect2, varscan2
- LAMC2 | c.3159G>A p.M1053I | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs781303442, COSV51460074; called by muse, mutect2, varscan2
- LAMC2 | c.3383C>T p.S1128F | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV51460087; called by muse, mutect2, varscan2
- LBP | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54139778; called by muse, mutect2, varscan2
- LCK | c.957G>A p.M319I | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV60742980; called by muse, mutect2, varscan2
- LCT | c.2261G>A p.G754E | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.715); catalogued as COSV51558297; called by muse, mutect2, varscan2
- LDHC | c.263A>G p.N88S | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55006209; called by muse, mutect2, varscan2
- LEPR | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 37/38 reads (97%) | catalogued as COSV60759159; called by muse, mutect2, varscan2
- LGALS7B | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100153420; called by mutect2, varscan2
- LLGL2 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755124108, COSV51417631; called by muse, mutect2, varscan2
- LMO1 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as COSV100231188; called by muse, mutect2, varscan2
- LPAR4 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV70913528; called by muse, mutect2, varscan2
- LPIN1 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 66/117 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs113391634, COSV56769707; called by muse, varscan2
- LRCH3 | c.1672T>C p.C558R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as COSV58397144; called by muse, mutect2, varscan2
- LRFN2 | c.2327G>A p.G776E | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0.296); catalogued as COSV57835208; called by muse, mutect2, varscan2
- LRFN2 | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1389358289, COSV100599756, COSV57835216; called by muse, mutect2, varscan2
- LRFN5 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53255753, COSV53262822; called by muse, varscan2
- LRIT1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs776008586, COSV64512551; called by muse, mutect2
- LRP1 | c.6524G>A p.R2175H | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs778549302, COSV54518627; called by mutect2, varscan2
- LRP1 | c.11935C>T p.R3979* | Nonsense Mutation (SNP) | VAF 42/56 reads (75%) | catalogued as rs775909658, COSV99677812; called by mutect2, varscan2
- LRP2 | c.3931C>T p.R1311C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs756651134, COSV55547502; called by muse, mutect2, varscan2
- LRRC4 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1471897285, COSV50819221; called by muse, mutect2, varscan2
- LRRC8D | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV61581455; called by muse, varscan2
- LRRIQ1 | c.1221C>A p.N407K | Missense Mutation (SNP) | VAF 115/192 reads (60%) | SIFT tolerated (0.81); PolyPhen benign (0.015); catalogued as rs373162982, COSV67839431; called by muse, mutect2, varscan2
- LRRIQ1 | c.3004C>T p.H1002Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.146); catalogued as COSV67839437; called by muse, mutect2, varscan2
- LSM11 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770812064, COSV53848038; called by muse, mutect2, varscan2
- LTN1 | c.3577A>G p.I1193V | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs775051449, COSV63735454; called by muse, mutect2, varscan2
- LY86 | c.137-1G>A p.X46_splice | Splice Site (SNP) | VAF 7/21 reads (33%) | catalogued as rs1288534062, COSV57911881; called by muse, mutect2, varscan2
- LYST | c.9315G>A p.K3105= | Splice Region (SNP) | VAF 31/62 reads (50%) | catalogued as COSV67714817; called by muse, mutect2, varscan2
- M1AP | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as rs1298475515, COSV51848495; called by muse, mutect2, varscan2
- MAD1L1 | c.1241T>C p.I414T | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV56249038; called by muse, mutect2, varscan2
- MAGEA12 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1556833673, COSV63295124; called by muse, mutect2, varscan2
- MAGEB6B | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs754418607; called by mutect2, varscan2
- MAGEC1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 82/226 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs866448898, COSV53567920; called by muse, mutect2, varscan2
- MAGEE2 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV64898591; called by muse, mutect2, varscan2
- MAGEL2 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs534021588, COSV58568286; called by mutect2, varscan2
- MAGT1 | c.617G>A p.R206Q (on ENST00000618282 / NM_001367916.1; = p.R238Q on NM_032121.5) | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1557216032, COSV63781409; called by muse, mutect2, varscan2
- MANBA | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.972); catalogued as COSV56967953; called by muse, mutect2, varscan2
- MAP1A | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765277558, COSV55805875; called by muse, mutect2, varscan2
- MAP3K9 | c.2674C>T p.P892S (on ENST00000554752 / NM_001284230.1; = p.P906S on NM_033141.4) | Missense Mutation (SNP) | VAF 65/326 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as COSV67122996; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as COSV51727877; called by muse, varscan2
- MAPT | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV52248335; called by muse, mutect2, varscan2
- MARCO | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59059196; called by muse, mutect2, varscan2
- MARK4 | c.437A>T p.Y146F | Missense Mutation (SNP) | VAF 95/159 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53469391; called by muse, mutect2, varscan2
- MAST4 | c.4307C>T p.P1436L (on ENST00000403625 / NM_001164664.2; = p.P1247L on NM_015183.3) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55125812; called by muse, mutect2
- MBD5 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as COSV68699103; called by muse, mutect2, varscan2
- MCAT | c.481G>C p.V161L | Missense Mutation (SNP) | VAF 183/293 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51793810; called by muse, mutect2, varscan2
- MCCC2 | c.1215T>A p.T405= | Splice Region (SNP) | VAF 16/24 reads (67%) | catalogued as COSV60157142; called by muse, mutect2, varscan2
- MDC1 | c.3278C>T p.P1093L | Missense Mutation (SNP) | VAF 94/339 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs372811207; called by muse, mutect2, varscan2
- MDFI | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 186/311 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57822011; called by muse, mutect2, varscan2
- MED12L | c.3908G>A p.G1303E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.295); catalogued as COSV56399464; called by muse, mutect2
- MEFV | c.2219T>G p.I740S | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV54828084; called by muse, mutect2, varscan2
- MEGF8 | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52103112; called by muse, mutect2, varscan2
- MERTK | c.2779G>A p.G927R | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV54932626; called by muse, mutect2, varscan2
- METTL17 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 135/321 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV100068772; called by muse, mutect2, varscan2
- METTL17 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 133/317 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs781577207, COSV100068776; called by muse, mutect2, varscan2
- METTL7B | c.627G>A p.W209* | Nonsense Mutation (SNP) | VAF 26/120 reads (22%) | catalogued as rs1432168767, COSV57701815; called by muse, mutect2, varscan2
- MFF | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 213/596 reads (36%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.883); catalogued as COSV58826871; called by muse, mutect2, varscan2
- MFSD11 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs980010430, COSV60629074; called by muse, mutect2, varscan2
- MGA | c.1581A>T p.E527D | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV54964072; called by mutect2, varscan2
- MGAM | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV72074620; called by muse, mutect2, varscan2
- MGAT1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 42/150 reads (28%) | PolyPhen benign (0.003); catalogued as COSV100286876; called by muse, mutect2, varscan2
- MGAT5 | c.1300T>A p.S434T | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.088); catalogued as COSV56101615; called by muse, mutect2, varscan2
- MGRN1 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 88/291 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.77); catalogued as COSV52154842; called by muse, mutect2, varscan2
- MICAL2 | c.4376C>T p.S1459F | Missense Mutation (SNP) | VAF 71/118 reads (60%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV56288949; called by muse, mutect2, varscan2
- MICAL2 | c.5791G>A p.E1931K | Missense Mutation (SNP) | VAF 62/95 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56288967; called by muse, mutect2, varscan2
- MICAL3 | c.4562C>T p.P1521L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV71588926; called by muse, mutect2, varscan2
- MITF | c.1447C>T p.L483F (on ENST00000448226 / NM_006722.3; = p.L383F on NM_000248.4) | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV58836362; called by muse, mutect2, varscan2
- MLXIP | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100038736, COSV59838234; called by muse, mutect2, varscan2
- MMP1 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs749993257, COSV59511988; called by muse, mutect2, varscan2
- MN1 | c.3058G>A p.D1020N | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.811); catalogued as rs968161766, COSV100180240, COSV56562647; called by muse, mutect2, varscan2
- MNT | c.1172T>C p.L391P | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs1259076973, COSV51514221; called by muse, mutect2, varscan2
- MON1A | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56563101; called by muse, mutect2, varscan2
- MRAP2 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV57631965; called by muse, mutect2, varscan2
- MRGPRE | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.453); catalogued as COSV67745592; called by muse, mutect2, varscan2
- MRGPRF | c.116C>G p.A39G | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs763966595, COSV57996376, COSV57996548; called by muse, mutect2, varscan2
- MROH5 | c.1242G>A p.W414* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV71303013; called by muse, mutect2, varscan2
- MRPL15 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.513); catalogued as COSV52638881; called by muse, mutect2, varscan2
- MRPL49 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1360383550, COSV99589334; called by muse, mutect2, varscan2
- MRPS34 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV51599412; called by muse, mutect2, varscan2
- MSLN | c.29T>C p.L10S | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs548280943, COSV67021350; called by muse, mutect2, varscan2
- MSLN | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 35/58 reads (60%) | catalogued as rs749372186, COSV53506803; called by muse, mutect2, varscan2
- MT2A | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV55330297, COSV99076160; called by mutect2, varscan2
- MT4 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as COSV54643113; called by muse, mutect2, varscan2
- MTERF3 | c.193T>G p.S65A | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.108); catalogued as COSV54634793; called by muse, mutect2, varscan2
- MTTP | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV55510285; called by muse, mutect2, varscan2
- MUC13 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV60701514; called by muse, mutect2, varscan2
- MUC16 | c.38990C>T p.P12997L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs1322483772, COSV67496924; called by muse, mutect2, varscan2
- MUC16 | c.33749T>C p.V11250A | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV67496933; called by muse, mutect2, varscan2
- MUC16 | c.21026C>T p.S7009F | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV67450400, COSV67455274; called by muse, mutect2, varscan2
- MUC16 | c.10022G>A p.G3341E | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs772256604, COSV67496949; called by muse, mutect2, varscan2
1,680 further variants in this file (757 protein-altering or splice-affecting, 859 silent, 64 other) are not listed here.
